Somatic mutation profile of tumor specimen TCGA-D6-A74Q-01A (aliquot TCGA-D6-A74Q-01A-11D-A34J-08) from TCGA case TCGA-D6-A74Q, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 67.6 years (24,702 days).
Specimen TCGA-D6-A74Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5104dce-1209-4994-acd2-fbb23a5dd656.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D6-A74Q-10A (Blood Derived Normal), aliquot TCGA-D6-A74Q-10A-02D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf38c551-8eab-4497-b098-52be498efcb1

The open-access MAF lists 461 somatic variants for this specimen: 333 protein-altering or splice-affecting, 121 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 280, Silent 121, Nonsense Mutation 29, Splice Site 8, Frame Shift Del 7, Splice Region 5, RNA 3, Intron 2, Nonstop Mutation 2, 3'UTR 1, 5'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 12/22 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913381, CM071585, CM973278, COSV58682998, COSV58690035, COSV58690777, COSV58726216; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 86/261 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PHYH | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894173, CM001297, COSV53816696; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 164/264 reads (62%) | catalogued as rs869312782, COSV52692559, COSV52721885, COSV53153630, COSV53758203; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.5836G>T p.G1946C (on ENST00000614293; = p.G1916C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55797467; called by muse, mutect2
- ABCA3 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as rs1278044377, CM040355, COSV57059294; called by muse, mutect2, varscan2
- ACAN | c.6367G>C p.D2123H | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs1257260023, COSV61357552; called by muse, mutect2
- ADAM19 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99978794; called by muse, mutect2, varscan2
- ADAMTS16 | c.487A>T p.T163S | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV99943466; called by muse, mutect2, varscan2
- ADAMTS18 | c.2116C>T p.P706S | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs753490416, COSV51418581; called by muse, mutect2, varscan2
- ADAMTS20 | c.4487G>T p.R1496M | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101239993; called by muse, mutect2, varscan2
- ADCY8 | c.728A>T p.Q243L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV99654904; called by muse, mutect2, varscan2
- ADGRB3 | c.3263C>A p.S1088* | Nonsense Mutation (SNP) | VAF 67/197 reads (34%) | catalogued as COSV99487229; called by muse, mutect2, varscan2
- AFDN | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 105/430 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770846848, COSV60042184, COSV60049837; called by muse, mutect2, varscan2
- AFF3 | c.1939T>A p.C647S | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.025); catalogued as COSV100420336; called by muse, mutect2, varscan2
- AGTR1 | c.446G>A p.C149Y | Missense Mutation (SNP) | VAF 77/218 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1020069665, COSV100837224, COSV62558480; called by muse, mutect2, varscan2
- AHCTF1 | c.3286A>T p.K1096* (on ENST00000366508; = p.K1070* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 31/124 reads (25%) | catalogued as COSV100403446, COSV100404594; called by muse, mutect2, varscan2
- AHNAK | c.16901G>T p.G5634V | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1352004574, COSV99950147; called by muse, mutect2, varscan2
- AHNAK | c.16900G>T p.G5634* | Nonsense Mutation (SNP) | VAF 53/144 reads (37%) | catalogued as COSV99950149; called by muse, mutect2, varscan2
- AJUBA | c.1084C>T p.Q362* | Nonsense Mutation (SNP) | VAF 79/127 reads (62%) | catalogued as COSV99401248; called by muse, mutect2, varscan2
- ALCAM | c.1076G>T p.S359I | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100065960; called by muse, mutect2, varscan2
- ALMS1 | c.12356C>T p.S4119F | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100044087; called by muse, mutect2, varscan2
- AMER3 | c.1427C>G p.P476R | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.458); catalogued as COSV100367001; called by muse, mutect2, varscan2
- ANKMY1 | c.758G>T p.C253F | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.357); catalogued as COSV99803550; called by muse, mutect2, varscan2
- ARFGEF3 | c.5548G>A p.D1850N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.188); catalogued as COSV52474408; called by muse, mutect2, varscan2
- ARHGAP22 | c.24G>T p.Q8H | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99985233, COSV99986211; called by muse, mutect2, varscan2
- ARHGAP9 | c.1754T>A p.V585E (on ENST00000393797 / NM_001319850.2; = p.V566E on NM_032496.4) | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99954818; called by muse, mutect2, varscan2
- ARHGEF19 | c.1627G>T p.A543S | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99580874; called by muse, mutect2, varscan2
- ATG4C | c.256A>T p.R86* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100508626; called by muse, mutect2, varscan2
- ATIC | c.1690G>T p.G564C | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99378307; called by muse, mutect2, varscan2
- BAZ2B | c.2010G>T p.M670I | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100601143; called by muse, mutect2, varscan2
- BRF2 | c.608G>T p.R203L | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as rs143386716, COSV99605182; called by muse, mutect2, varscan2
- BRS3 | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146164598, COSV101036705, COSV65710950; called by muse, mutect2, varscan2
- BUB1 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100241747; called by muse, mutect2, varscan2
- C14orf39 | c.1397A>T p.E466V | Missense Mutation (SNP) | VAF 130/181 reads (72%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV100408191; called by muse, mutect2, varscan2
- C7 | c.86A>G p.Q29R | Missense Mutation (SNP) | VAF 29/39 reads (74%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1311381353, COSV100496753; called by muse, mutect2, varscan2
- CA11 | c.625C>G p.R209G | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV99320915; called by muse, mutect2, varscan2
- CACNA1A | c.361C>G p.L121V | Missense Mutation (SNP) | VAF 82/238 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100803432; called by muse, mutect2, varscan2
- CAMK1G | c.649C>G p.P217A | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV99152346; called by muse, mutect2, varscan2
- CAPRIN2 | c.2139G>C p.E713D | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV99195775; called by muse, mutect2, varscan2
- CAVIN2 | c.10G>C p.D4H | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs759542197, COSV100414403; called by muse, mutect2, varscan2
- CCDC42 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 63/95 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99549954; called by muse, mutect2, varscan2
- CCNB3 | c.2941G>A p.A981T | Missense Mutation (SNP) | VAF 52/83 reads (63%) | SIFT tolerated (0.62); PolyPhen benign (0.035); catalogued as rs782383616, COSV99330056; called by muse, mutect2, varscan2
- CD163 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 100/235 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as COSV100776191; called by muse, mutect2, varscan2
- CD1C | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 159/356 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as rs1045058762, COSV100939479; called by muse, mutect2, varscan2
- CDCA7 | c.308A>G p.N103S (on ENST00000347703 / NM_145810.3; = p.N182S on NM_031942.5) | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV60720215; called by muse, mutect2, varscan2
- CHD9 | c.2726G>C p.G909A | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV99529895; called by muse, mutect2, varscan2
- CHRNA9 | c.96G>C p.Q32H | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.049); catalogued as COSV100039172; called by muse, mutect2
- CLEC1B | c.606A>T p.K202N | Missense Mutation (SNP) | VAF 90/198 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV100046199; called by muse, mutect2, varscan2
- CNTNAP2 | c.3182C>T p.P1061L | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs778596213, COSV100673842, COSV62169601; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL27A1 | c.2827G>A p.G943R | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100621399; called by muse, mutect2, varscan2
- COL4A2 | c.4229G>A p.R1410Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.19); catalogued as rs1004346642, COSV64629756; called by muse, varscan2
- COL7A1 | c.7814G>T p.G2605V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99866469; called by muse, mutect2, varscan2
- COL7A1 | c.7813G>T p.G2605* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as COSV56476024, COSV99866471; called by muse, mutect2, varscan2
- CPNE9 | c.1183C>G p.R395G | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV56068053, COSV99808553; called by muse, mutect2, varscan2
- CYP2C9 | c.1471T>A p.*491Rext*42 | Nonstop Mutation (SNP) | VAF 76/118 reads (64%) | catalogued as rs879131618, COSV99583349; called by muse, mutect2, varscan2
- DBF4B | c.1223G>A p.W408* | Nonsense Mutation (SNP) | VAF 22/76 reads (29%) | catalogued as COSV100154772; called by muse, mutect2, varscan2
- DCAF4L2 | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100151379; called by muse, mutect2, varscan2
- DCBLD1 | c.574G>T p.G192* | Nonsense Mutation (SNP) | VAF 30/102 reads (29%) | catalogued as COSV99758279; called by muse, mutect2, varscan2
- DCHS1 | c.4879C>G p.P1627A | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1159342978, COSV100202715; called by muse, mutect2, varscan2
- DCLRE1C | c.389C>A p.T130N (on ENST00000378278 / NM_001350965.2; = p.T15N on NM_022487.4) | Missense Mutation (SNP) | VAF 59/192 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.208); catalogued as COSV100740015, COSV63182063; called by muse, mutect2, varscan2
- DDB1 | c.1430G>A p.R477K | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs749306073, COSV100074911; called by muse, mutect2, varscan2
- DDX54 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1442657033, COSV100014274; called by muse, mutect2, varscan2
- DNAH1 | c.6896C>A p.P2299Q | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101327318, COSV70235843; called by muse, mutect2, varscan2
- DPP6 | c.1350A>T p.R450S (on ENST00000377770 / NM_001364500.2; = p.R388S on NM_001936.5) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100128759; called by muse, mutect2
- DPPA4 | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100169785; called by muse, mutect2, varscan2
- DPY19L2 | c.2024C>G p.S675C | Missense Mutation (SNP) | VAF 97/237 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100194169; called by muse, mutect2, varscan2
- DRC1 | c.928C>G p.Q310E | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV99985811; called by muse, mutect2, varscan2
- DST | c.15966C>G p.N5322K (on ENST00000361203 / NM_001374722.1; = p.N2910K on NM_015548.5) | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99760928; called by muse, mutect2
- EDEM2 | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65713110; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2254C>T p.R752W | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs377161686; called by muse, mutect2, varscan2
- EFCAB7 | c.672C>G p.F224L | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100937736, COSV64315120; called by muse, mutect2
- EIF2B4 | c.368G>T p.G123V (on ENST00000347454 / NM_001034116.2; = p.G122V on NM_015636.3) | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.221); catalogued as COSV99278123; called by muse, mutect2
- EME1 | c.218C>A p.T73N | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.383); catalogued as COSV99869207; called by muse, mutect2, varscan2
- ENOX1 | c.1574T>A p.L525* | Nonsense Mutation (SNP) | VAF 71/204 reads (35%) | catalogued as COSV99817565; called by muse, mutect2, varscan2
- EPB41L5 | c.1159A>T p.T387S | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV99759334; called by muse, mutect2, varscan2
- EXD3 | c.216G>T p.E72D | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV100574062; called by muse, mutect2
- F2RL3 | c.1017C>G p.I339M | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV50185377; called by muse, mutect2, varscan2
- FAM135B | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 22/66 reads (33%) | catalogued as COSV52731308, COSV99428561; called by muse, mutect2, varscan2
- FAM83G | c.13C>G p.Q5E | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100525597; called by muse, mutect2
- FAM98A | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 34/244 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV99479606; called by muse, mutect2, varscan2
- FAP | c.1122C>A p.Y374* | Nonsense Mutation (SNP) | VAF 18/57 reads (32%) | catalogued as COSV99502623; called by muse, mutect2, varscan2
- FAT2 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as rs374282108; called by muse, mutect2, varscan2
- FBLN2 | c.2606G>T p.C869F | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55488616; called by muse, mutect2, varscan2
- FER1L5 | c.5425G>T p.G1809W (on ENST00000623019; = p.G1773W on NM_001293083.2) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99383726; called by muse, mutect2, varscan2
- FGL2 | c.137G>A p.R46K | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV50382414; called by muse, mutect2
- FHOD3 | c.405+2T>A p.X135_splice | Splice Site (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99943502; called by muse, mutect2, varscan2
- FKBP8 | c.291G>T p.L97= | Splice Region (SNP) | VAF 7/49 reads (14%) | catalogued as COSV99724337; called by muse, mutect2, varscan2
- FLG | c.4163G>T p.R1388L | Missense Mutation (SNP) | VAF 52/588 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV100912398; called by muse, mutect2
- FMN2 | c.458G>A p.R153K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.005); catalogued as rs1217742857, COSV100147747; called by muse, mutect2, varscan2
- FMN2 | c.459G>T p.R153S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.005); catalogued as COSV100142328; called by muse, mutect2, varscan2
- FRMPD2 | c.996C>G p.T332= | Splice Region (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100564307; called by muse, varscan2
- GABRG1 | c.901G>T p.A301S | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV99778900; called by muse, mutect2, varscan2
- GABRQ | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100941430, COSV100941451; called by muse, mutect2, varscan2
- GCK | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM082786, COSV61754908; called by muse, mutect2, varscan2
- GH2 | c.375C>A p.N125K | Missense Mutation (SNP) | VAF 100/158 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV60427007; called by muse, mutect2, varscan2
- GPR108 | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 20/54 reads (37%) | catalogued as COSV99901605; called by muse, mutect2, varscan2
- GPR12 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1028885158, COSV101198039; called by muse, mutect2, varscan2
- GRTP1 | c.551G>A p.R184K | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.057); catalogued as COSV100391467; called by muse, mutect2
- GSAP | c.1990C>T p.H664Y | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.253); catalogued as COSV99990497, COSV99990578; called by muse, mutect2, varscan2
- GSTM4 | c.456G>A p.K152= | Splice Region (SNP) | VAF 10/198 reads (5%) | catalogued as COSV100264350; called by muse, mutect2
- GTF3C6 | c.361+2T>C p.X121_splice | Splice Site (SNP) | VAF 15/47 reads (32%) | catalogued as COSV100328831; called by muse, mutect2, varscan2
- H2AP | c.99C>A p.D33E | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.26); PolyPhen benign (0.303); catalogued as COSV100586957; called by muse, mutect2, varscan2
- H2BC10 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 10/160 reads (6%) | catalogued as COSV100010408, COSV59952776, COSV59953804; called by muse, mutect2
- HDAC11 | c.749T>A p.L250Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV99850106; called by muse, mutect2, varscan2
- HDC | c.156C>A p.D52E | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99984375; called by muse, mutect2, varscan2
- HERC2 | c.12150C>G p.H4050Q | Missense Mutation (SNP) | VAF 76/218 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99877535; called by muse, mutect2, varscan2
- HINT3 | c.358A>G p.R120G | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV99996243; called by muse, mutect2, varscan2
- HNRNPM | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV100334914; called by muse, mutect2
- HNRNPU | c.1214G>A p.R405K (on ENST00000283179; = p.R467K on NM_004501.3) | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99310792; called by muse, mutect2, varscan2
- HPF1 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.046); catalogued as rs372065647; called by muse, mutect2, varscan2
- HSCB | c.635A>C p.K212T | Missense Mutation (SNP) | VAF 91/274 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99319802; called by muse, mutect2, varscan2
- HSPA12A | c.572A>T p.E191V | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV100980016; called by muse, mutect2, varscan2
- IGF2BP3 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs267601464, COSV99325983; called by muse, mutect2, varscan2
- IQCA1 | c.597G>T p.M199I | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99610562; called by muse, mutect2
- IRF4 | c.1340C>A p.S447Y | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV101110980; called by muse, mutect2, varscan2
- ITGA8 | c.1465G>C p.V489L | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV100959899; called by muse, mutect2, varscan2
- KHDRBS2 | c.655G>T p.G219C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV55495046, COSV99838541; called by muse, mutect2, varscan2
- KIAA1217 | c.4393G>A p.E1465K | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1052365763, COSV100287467; called by muse, mutect2, varscan2
- LAMA3 | c.2196G>C p.E732D | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100557817; called by muse, mutect2, varscan2
- LAMA4 | c.1942A>G p.T648A (on ENST00000230538 / NM_001105206.3; = p.T641A on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated (0.88); PolyPhen benign (0.163); catalogued as COSV100039758; called by muse, mutect2, varscan2
- LAMC2 | c.2962G>C p.D988H | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV51452545; called by muse, mutect2, varscan2
- LEPR | c.2601G>T p.M867I | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60750358, COSV60757388; called by muse, mutect2, varscan2
- LGSN | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV101040781; called by muse, mutect2, varscan2
- LINGO2 | c.857G>T p.S286I | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.278); catalogued as COSV100430184, COSV100431371; called by muse, mutect2, varscan2
- LMOD3 | c.843C>G p.N281K | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV101342040; called by muse, mutect2, varscan2
- LONRF2 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.097); catalogued as COSV101111077; called by muse, mutect2
- LPA | c.4652G>T p.C1551F | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100306063; called by muse, mutect2, varscan2
- LRCH2 | c.2146C>T p.L716F | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100406905, COSV100407753; called by muse, mutect2, varscan2
- LRFN3 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99873684; called by muse, mutect2
- LRFN4 | c.1335G>C p.E445D | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as rs765774004, COSV100540921; called by muse, mutect2, varscan2
- LRP12 | c.1643C>T p.S548L | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1344260913, COSV99408482; called by muse, mutect2, varscan2
- LRP1B | c.3460G>T p.E1154* | Nonsense Mutation (SNP) | VAF 42/161 reads (26%) | catalogued as COSV101262159; called by muse, mutect2, varscan2
- LRP1B | c.1692C>A p.H564Q | Missense Mutation (SNP) | VAF 77/250 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV101253004, COSV67234180; called by muse, mutect2, varscan2
- LRP1B | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs866355058, COSV67273796; called by muse, mutect2, varscan2
- LRP2 | c.7051G>T p.G2351C | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99790695; called by muse, mutect2, varscan2
- LRRC4B | c.1496C>A p.P499H | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV100976079; called by muse, mutect2
- LRRC6 | c.115A>G p.I39V | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as rs766328211, COSV99138795; called by muse, mutect2, varscan2
- MATK | c.335C>T p.S112F (on ENST00000310132 / NM_139355.3; = p.S113F on NM_002378.4) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.434); catalogued as COSV100036353; called by muse, mutect2, varscan2
- MBD6 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.771); catalogued as rs769111092, COSV100851861; called by muse, mutect2, varscan2
- MC1R | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.697); catalogued as rs764430047, COSV100206158; called by muse, mutect2, varscan2
- MC5R | c.796C>A p.Q266K | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV100229201; called by muse, mutect2, varscan2
- MEGF9 | c.1089A>T p.K363N | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV100879570; called by muse, mutect2, varscan2
- MGAT5B | c.1393G>A p.V465M | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772934864, COSV100049097; called by muse, mutect2, varscan2
- MMP26 | c.109del p.H37Ifs*5 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as COSV56173306; called by mutect2, pindel, varscan2
- MORN3 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs1166934064, COSV100804522; called by muse, mutect2
- MPDZ | c.2644C>G p.P882A | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100065254; called by muse, mutect2, varscan2
- MPHOSPH8 | c.922C>A p.H308N | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV100825246; called by muse, mutect2, varscan2
- MPP2 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.506); catalogued as COSV99290939; called by muse, mutect2, varscan2
- MRC1 | c.358G>A p.G120S | Missense Mutation (SNP) | VAF 169/465 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs372055031; called by muse, mutect2, varscan2
- MYOM1 | c.1513G>C p.E505Q | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV99868831; called by muse, mutect2, varscan2
- MYOM3 | c.2783C>T p.S928L | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV100294058; called by muse, mutect2
- MYPN | c.1949C>G p.P650R | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100590730; called by muse, mutect2, varscan2
- NAGPA | c.1276+1G>A p.X426_splice | Splice Site (SNP) | VAF 16/46 reads (35%) | catalogued as rs762744538, COSV100393132; called by muse, mutect2, varscan2
- NEK11 | c.1391G>C p.G464A | Missense Mutation (SNP) | VAF 71/222 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.112); catalogued as COSV100797950; called by muse, mutect2, varscan2
- NEXMIF | c.3893T>C p.M1298T | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as COSV99282222; called by muse, mutect2, varscan2
- NFKBIZ | c.1205C>G p.S402* | Nonsense Mutation (SNP) | VAF 10/96 reads (10%) | catalogued as COSV100397292; called by muse, mutect2, varscan2
- NOS1 | c.3898G>C p.E1300Q | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as COSV100501584, COSV57607538; called by muse, mutect2, varscan2
- NPFFR2 | c.755C>A p.P252H | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100441444; called by muse, mutect2, varscan2
- NR4A2 | c.1411C>T p.H471Y | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99045214; called by muse, mutect2, varscan2
- NR5A2 | c.562G>T p.A188S (on ENST00000367362 / NM_205860.3; = p.A142S on NM_003822.5) | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV99371804; called by muse, mutect2, varscan2
- NRIP1 | c.733A>G p.S245G | Missense Mutation (SNP) | VAF 80/290 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100013254; called by muse, mutect2, varscan2
- ODF2 | c.447G>C p.Q149H (on ENST00000434106 / NM_153433.2; = p.Q125H on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.718); catalogued as rs1253421797, COSV100655022; called by muse, mutect2
- OLFM2 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV99322138; called by muse, mutect2, varscan2
- OR10G4 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100305046; called by muse, mutect2, varscan2
- OR10G8 | c.681C>G p.I227M | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV101461895; called by muse, mutect2, varscan2
- OR11H6 | c.626C>A p.S209Y | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV100210005; called by muse, mutect2, varscan2
- OR1I1 | c.52T>A p.S18T | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV99264941; called by muse, mutect2, varscan2
- OR1J4 | c.494A>C p.Q165P | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.053); catalogued as COSV61589622; called by muse, mutect2, varscan2
- OR2M4 | c.292G>T p.G98* | Nonsense Mutation (SNP) | VAF 55/115 reads (48%) | catalogued as COSV60709733; called by muse, mutect2, varscan2
- OR2T8 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.103); catalogued as rs758294510, COSV100177951, COSV100178597; called by mutect2, varscan2
- OR4A5 | c.393del p.T132Pfs*3 | Frame Shift Del (DEL) | VAF 34/111 reads (31%) | catalogued as COSV60521612; called by mutect2, pindel, varscan2
- OR4C15 | c.765C>G p.N255K (on ENST00000314644; = p.N201K on NM_001001920.2) | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as COSV100116192; called by muse, mutect2
- OR4D9 | c.589C>A p.L197I | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as rs1466644804, COSV100260039; called by muse, mutect2, varscan2
- OR4M1 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762783313, COSV60061014; called by muse, mutect2, varscan2
- OR4S2 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100412857; called by muse, mutect2, varscan2
- OR51D1 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766678969, COSV62913821; called by muse, mutect2, varscan2
- OR5D13 | c.481C>T p.L161F | Missense Mutation (SNP) | VAF 75/219 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.06); catalogued as COSV100687116; called by muse, mutect2, varscan2
- OR6N1 | c.336C>G p.C112W | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100625327; called by muse, mutect2, varscan2
- OR6T1 | c.20C>A p.T7N | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as COSV100190241, COSV58308526; called by muse, mutect2, varscan2
- OR8D1 | c.689C>A p.S230Y | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100766688, COSV63442638; called by muse, mutect2, varscan2
- OTOGL | c.2891A>G p.Y964C (on ENST00000547103; = p.Y955C on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101509536; called by muse, mutect2, varscan2
- OTOGL | c.3399G>C p.K1133N (on ENST00000547103; = p.K1124N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101509537, COSV72005597, COSV72007572; called by muse, mutect2
- P2RY1 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); catalogued as rs375587095, COSV100521815; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1939G>A p.E647K (on ENST00000259318 / NM_001136562.3; = p.E878K on NM_007203.5) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.468); catalogued as COSV99395901; called by muse, mutect2, varscan2
- PAPPA2 | c.3568C>T p.Q1190* | Nonsense Mutation (SNP) | VAF 19/117 reads (16%) | catalogued as COSV62811153; called by muse, mutect2, varscan2
- PAX8 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99640211; called by muse, mutect2
- PCDH10 | c.1311C>A p.D437E | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV99994745; called by muse, mutect2, varscan2
- PCDH10 | c.1841C>G p.A614G | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.997); catalogued as COSV99994752; called by muse, mutect2, varscan2
- PCDH7 | c.2921G>T p.S974I | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.309); catalogued as COSV100688750; called by muse, mutect2, varscan2
- PCDHB12 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 53/92 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as COSV99507993; called by muse, mutect2, varscan2
- PCDHB5 | c.1066C>A p.P356T | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs1554275921, COSV99169738; called by muse, mutect2, varscan2
- PCDHB5 | c.1067C>A p.P356Q | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV50648019, COSV50667179; called by muse, mutect2, varscan2
- PCDHGA3 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 74/145 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as rs1281454137, COSV99549108; called by muse, mutect2, varscan2
- PCLO | c.3209C>T p.S1070F | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100439243; called by muse, mutect2, varscan2
- PCNX3 | c.2392G>T p.G798C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.57); catalogued as COSV63141138; called by muse, mutect2, varscan2
- PDE1B | c.601A>G p.T201A | Missense Mutation (SNP) | VAF 385/966 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV54492597, COSV99673102; called by muse, varscan2
- PDS5A | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100337605; called by muse, mutect2, varscan2
- PGM2L1 | c.1099G>C p.D367H | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV53346446; called by muse, mutect2
- PHKA1 | c.3385G>T p.E1129* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100264055; called by muse, mutect2, varscan2
- PKHD1 | c.9706C>G p.P3236A | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV100584909, COSV61876962; called by muse, mutect2, varscan2
- PKHD1 | c.4601G>C p.S1534T | Missense Mutation (SNP) | VAF 66/104 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV100584911, COSV61895893; called by muse, mutect2, varscan2
- PLBD1 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99554877; called by muse, mutect2, varscan2
- PLCZ1 | c.1392A>T p.L464F | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99857145; called by muse, mutect2, varscan2
- PLCZ1 | c.574C>A p.L192I | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99857148; called by muse, mutect2, varscan2
- PLD1 | c.465G>T p.E155D | Missense Mutation (SNP) | VAF 80/235 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.033); catalogued as COSV100579099; called by muse, mutect2, varscan2
- PLEKHG4B | c.3421G>A p.A1141T (on ENST00000283426; = p.A1497T on NM_052909.5) | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as COSV99361301; called by muse, mutect2, varscan2
- PLEKHM1 | c.2312T>A p.L771Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV101378927; called by mutect2, varscan2
- POLR3F | c.453G>T p.M151I | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV101112306; called by muse, mutect2, varscan2
- PPARA | c.129G>T p.E43D | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as COSV99416018; called by muse, mutect2, varscan2
- PPM1E | c.2186G>C p.G729A | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV100376749; called by muse, mutect2, varscan2
- PRDM13 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.196); catalogued as COSV100980598; called by muse, mutect2, varscan2
- PRKAR2B | c.335G>T p.R112L | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV55925772, COSV99708791; called by muse, mutect2, varscan2
- PRPF38B | c.594G>T p.M198I | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.376); catalogued as COSV100898355, COSV64223686; called by muse, mutect2, varscan2
- PRPF40A | c.2423G>T p.R808L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101344245, COSV68356840; called by muse, mutect2, varscan2
- PRSS58 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as COSV101616180; called by muse, mutect2, varscan2
- PTGIR | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV99355116; called by muse, mutect2, varscan2
- PTPRD | c.5701C>A p.L1901I | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100647660; called by muse, mutect2, varscan2
- PTPRO | c.3381G>T p.K1127N (on ENST00000281171 / NM_030667.3; = p.K1099N on NM_002848.4) | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.7); catalogued as COSV99842040; called by muse, mutect2, varscan2
- PTPRS | c.118A>G p.K40E | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1427468626, COSV53618239, COSV99512861; called by muse, mutect2, varscan2
- PWWP3B | c.1868T>C p.I623T | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV100531701, COSV61801265; called by muse, mutect2, varscan2
- RARG | c.914G>T p.G305V | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100553775, COSV58434546; called by muse, mutect2, varscan2
- RBM26 | c.2956G>C p.D986H (on ENST00000438737 / NM_001366735.2; = p.D959H on NM_022118.5) | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.667); catalogued as COSV99936726; called by muse, mutect2, varscan2
- RBM5 | c.695-2A>G p.X232_splice | Splice Site (SNP) | VAF 65/151 reads (43%) | catalogued as COSV100762547; called by muse, mutect2, varscan2
- RCSD1 | c.728C>A p.P243H | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.397); catalogued as COSV100827822, COSV63261346; called by muse, mutect2, varscan2
- RECQL5 | c.1950C>G p.L650= | Splice Region (SNP) | VAF 10/79 reads (13%) | catalogued as rs1265916800, COSV100511733, COSV100512422; called by muse, mutect2, varscan2
- RFX6 | c.2743C>A p.P915T | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100264425; called by muse, mutect2, varscan2
- RGS9 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV99288219; called by muse, mutect2
- RNF128 | c.221A>T p.N74I | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV100176562; called by muse, mutect2, varscan2
- ROS1 | c.5713G>T p.E1905* | Nonsense Mutation (SNP) | VAF 75/263 reads (29%) | catalogued as COSV63853244, COSV63860799; called by muse, mutect2, varscan2
- RPGRIP1L | c.108G>A p.M36I | Missense Mutation (SNP) | VAF 79/271 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100047041; called by muse, mutect2, varscan2
- RPRD2 | c.3301G>A p.E1101K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV100955439; called by muse, mutect2, varscan2
- RUNX3 | c.188C>A p.A63E | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV100137159; called by muse, mutect2, varscan2
- RYR2 | c.1865G>T p.G622V | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1487120980, COSV100773288, COSV63711919; called by muse, mutect2, varscan2
- RYR2 | c.12837G>T p.M4279I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as COSV63675045; called by muse, mutect2, varscan2
- SAAL1 | c.1043-2A>T p.X348_splice | Splice Site (SNP) | VAF 23/57 reads (40%) | catalogued as COSV55516484; called by muse, mutect2, varscan2
- SAMD11 | c.457C>G p.R153G | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as COSV100574728; called by muse, varscan2
- SAMD9L | c.1886G>T p.R629L | Missense Mutation (SNP) | VAF 53/241 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs142436298, COSV100560484; called by muse, mutect2, varscan2
- SCN10A | c.2726A>T p.N909I | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV101479585; called by muse, mutect2, varscan2
- SCN4A | c.4846G>A p.D1616N | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101438712; called by muse, mutect2, varscan2
- SCN9A | c.465C>T p.V155= | Splice Region (SNP) | VAF 6/14 reads (43%) | catalogued as rs754275081, COSV57599105; called by muse, mutect2, varscan2
- SEMA4B | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100203317; called by muse, mutect2, varscan2
- SEMA6C | c.1033G>T p.G345C | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100501655; called by muse, mutect2, varscan2
- SH3PXD2A | c.1636G>C p.D546H (on ENST00000369774 / NM_001365079.1; = p.D518H on NM_014631.2) | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as COSV100280585; called by muse, mutect2, varscan2
- SHBG | c.338G>T p.W113L | Missense Mutation (SNP) | VAF 57/80 reads (71%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as COSV52647336, COSV99352335; called by muse, mutect2, varscan2
- SHCBP1 | c.449G>T p.C150F | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.425); catalogued as COSV100317602; called by muse, mutect2, varscan2
- SIGLEC1 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1412345517, COSV99171473; called by muse, mutect2, varscan2
- SIGLEC6 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100585802; called by muse, mutect2, varscan2
- SLC14A2 | c.690G>T p.K230N | Missense Mutation (SNP) | VAF 125/294 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV99676314; called by muse, mutect2, varscan2
- SLC15A1 | c.2032A>T p.I678F | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.883); catalogued as COSV100919545; called by muse, mutect2, varscan2
- SLC16A13 | c.1049G>T p.S350I | Missense Mutation (SNP) | VAF 107/195 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100338779; called by muse, mutect2, varscan2
- SLC22A16 | c.132G>T p.M44I | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV100398035; called by muse, mutect2, varscan2
- SLC2A13 | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 37/169 reads (22%) | catalogued as COSV99787363; called by muse, mutect2, varscan2
- SLC7A14 | c.1331T>C p.L444S | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV99201150; called by mutect2, varscan2
- SLC8A2 | c.1345G>T p.G449C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99370388; called by muse, mutect2, varscan2
- SNTG1 | c.1127G>T p.S376I | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV99386777; called by muse, mutect2, varscan2
- SP7 | c.634G>T p.A212S | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as rs758248289, COSV100382137; called by muse, mutect2, varscan2
- SRSF2 | c.140G>T p.R47L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); catalogued as COSV100334359, COSV57975806; called by muse, mutect2, varscan2
- STK31 | c.1511A>T p.D504V | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as COSV100670066; called by muse, mutect2, varscan2
- STK31 | c.3001G>C p.E1001Q | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV100670069, COSV63459410; called by muse, mutect2, varscan2
- STN1 | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV99830384; called by muse, mutect2, varscan2
- STYXL2 | c.2997C>A p.N999K | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99610043; called by muse, mutect2, varscan2
- SVOPL | c.982G>A p.G328R (on ENST00000419765; = p.G176R on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV55988501; called by muse, mutect2, varscan2
- SVOPL | c.578C>A p.S193Y (on ENST00000419765; = p.S41Y on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.191); catalogued as COSV99939786; called by muse, mutect2, varscan2
- SYNE1 | c.17367G>T p.K5789N (on ENST00000367255 / NM_182961.4; = p.K5718N on NM_033071.3) | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99583625; called by muse, mutect2, varscan2
- SYNE2 | c.4801C>G p.L1601V | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100648619; called by muse, mutect2, varscan2
- SYT4 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as COSV99674572; called by muse, mutect2, varscan2
- SYTL1 | c.1135G>T p.E379* (on ENST00000543823; = p.E367* on NM_032872.3) | Nonsense Mutation (SNP) | VAF 8/61 reads (13%) | catalogued as COSV100539538, COSV100539663; called by muse, mutect2, varscan2
- TAF1C | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.804); catalogued as rs747153539, COSV58989663; called by muse, mutect2, varscan2
- TBC1D14 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as COSV101299082; called by muse, mutect2
- TBC1D8 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.061); catalogued as COSV100964675; called by muse, mutect2, varscan2
- TCAIM | c.1251-1G>A p.X417_splice | Splice Site (SNP) | VAF 21/43 reads (49%) | catalogued as COSV100703456; called by muse, mutect2
- TECPR1 | c.2237G>A p.S746N | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as COSV101130822; called by muse, mutect2
- TMEM266 | c.1259C>G p.S420C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.694); catalogued as rs1193010394, COSV101189681; called by muse, mutect2, varscan2
- TMEM31 | c.216A>T p.E72D | Missense Mutation (SNP) | VAF 57/88 reads (65%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as COSV100129136; called by muse, mutect2, varscan2
- TMF1 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as rs371091215, COSV101275480; called by muse, mutect2, varscan2
- TRBC2 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); catalogued as rs782558931; called by muse, mutect2, varscan2
- TRIM36 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99142879; called by muse, mutect2, varscan2
- TRPC5 | c.2054G>C p.R685T | Missense Mutation (SNP) | VAF 71/110 reads (65%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV99463225; called by muse, mutect2, varscan2
- TSHZ3 | c.940G>C p.A314P | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.332); catalogued as rs776184849, COSV53664089, COSV53673939, COSV99553111; called by muse, mutect2
- TSPAN5 | c.145A>C p.N49H | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99995968; called by muse, mutect2, varscan2
- TSPYL5 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.101); catalogued as rs960194041, COSV59070957; called by muse, mutect2, varscan2
- TTC21A | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.534); catalogued as COSV100087791; called by muse, mutect2, varscan2
- TTC7B | c.1833G>C p.Q611H | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.965); catalogued as COSV100128742; called by muse, mutect2, varscan2
- TTN | c.27601G>C p.A9201P (on ENST00000591111; = p.A8274P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/188 reads (35%) | PolyPhen possibly damaging (0.731); catalogued as COSV100634872; called by muse, mutect2, varscan2
- TTN | c.4993G>A p.G1665R (on ENST00000591111; = p.G1619R on NM_003319.4) | Missense Mutation (SNP) | VAF 40/121 reads (33%) | PolyPhen probably damaging (1); catalogued as COSV100634873; called by muse, mutect2, varscan2
- TUBA1B | c.1111G>T p.V371L | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.995); catalogued as COSV100254246; called by muse, mutect2, varscan2
- TUBGCP4 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.137); catalogued as COSV99539543; called by muse, mutect2
- U2AF1L4 | c.69G>C p.K23N | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99495505; called by muse, mutect2
- UBA7 | c.299G>C p.R100T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100339901; called by muse, mutect2, varscan2
- ULK1 | c.2929G>T p.E977* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100417375; called by muse, mutect2, varscan2
- ULK4 | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as COSV100095816; called by muse, mutect2, varscan2
- UNC13C | c.5330C>T p.A1777V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99524116; called by muse, mutect2, varscan2
- UNC5C | c.2345C>G p.T782S | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.912); catalogued as rs1243743837, COSV101498076; called by muse, mutect2, varscan2
- UPF1 | c.1835C>T p.T612I (on ENST00000599848 / NM_001297549.2; = p.T601I on NM_002911.4) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV53196193, COSV99440580; called by muse, mutect2, varscan2
- USH2A | c.10168G>T p.G3390* | Nonsense Mutation (SNP) | VAF 15/101 reads (15%) | catalogued as COSV100244025; called by muse, mutect2
- USH2A | c.9379C>T p.Q3127* | Nonsense Mutation (SNP) | VAF 7/116 reads (6%) | catalogued as COSV100244026; called by muse, mutect2
- UTRN | c.4943T>C p.M1648T | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV100840751; called by muse, mutect2, varscan2
- VAV3 | c.1173+1G>A p.X391_splice | Splice Site (SNP) | VAF 11/27 reads (41%) | catalogued as rs1451767382, COSV100579336, COSV100580513; called by muse, mutect2, varscan2
- VPS13D | c.13147C>T p.Q4383* | Nonsense Mutation (SNP) | VAF 37/121 reads (31%) | catalogued as COSV99170064; called by muse, mutect2, varscan2
- WDR17 | c.1009A>C p.N337H | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.316); catalogued as COSV99708467; called by muse, mutect2, varscan2
- WDR17 | c.2135C>A p.P712Q | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99708469; called by muse, mutect2, varscan2
- WDR47 | c.1901C>T p.A634V (on ENST00000369962 / NM_001142551.2; = p.A635V on NM_014969.5) | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.122); catalogued as COSV100728490; called by muse, mutect2, varscan2
- WDR49 | c.688A>T p.N230Y (on ENST00000308378 / NM_001366158.1; = p.N571Y on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV100394040; called by muse, mutect2, varscan2
- WDR70 | c.1639A>G p.T547A | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV99460864; called by muse, mutect2, varscan2
- WNK4 | c.1861T>A p.S621T | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV99891766; called by muse, mutect2, varscan2
- XIRP2 | c.1762G>C p.E588Q (on ENST00000628543; = p.E763Q on NM_152381.6) | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.842); catalogued as COSV99748787; called by muse, mutect2
- ZC3H4 | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.96); catalogued as COSV99452973; called by muse, mutect2, varscan2
- ZFHX4 | c.370G>T p.V124L | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99267420; called by muse, mutect2, varscan2
- ZIC1 | c.68A>T p.H23L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.275); catalogued as COSV99292580; called by muse, mutect2, varscan2
- ZNF106 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs148277728; called by muse, mutect2
- ZNF385D | c.502G>T p.V168F | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT tolerated (0.67); PolyPhen benign (0.071); catalogued as COSV55764965, COSV99876729; called by muse, mutect2, varscan2
- ZNF43 | c.2429A>T p.*810Lext*23 | Nonstop Mutation (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100731999; called by muse, mutect2, varscan2
- ZNF492 | c.1002G>T p.E334D | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as COSV101514075; called by mutect2, varscan2
- ZNF497 | c.134C>A p.T45K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV54053207, COSV99568780; called by muse, mutect2, varscan2
- ZNF527 | c.105G>C p.Q35H | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62233460, COSV62237952; called by muse, mutect2, varscan2
- ZNF532 | c.2896G>C p.E966Q | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100267299; called by muse, mutect2
- ZNF676 | c.1789G>T p.E597* (on ENST00000650058; = p.E565* on NM_001001411.3) | Nonsense Mutation (SNP) | VAF 33/96 reads (34%) | catalogued as COSV101236376; called by muse, mutect2, varscan2
- ZNF839 | c.1126C>G p.Q376E (on ENST00000558850 / NM_001267827.1; = p.Q492E on NM_018335.5) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV99216492; called by muse, mutect2, varscan2
- ZNF880 | c.788C>T p.T263I | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101425024; called by muse, mutect2, varscan2
- ZP2 | c.352A>G p.I118V | Missense Mutation (SNP) | VAF 59/188 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.105); catalogued as COSV99559917; called by muse, mutect2, varscan2
- ZRANB2 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV99639900; called by muse, mutect2, varscan2
- CBWD5 | c.1041G>A p.W347* (on ENST00000382405 / NM_001330668.1; = p.W299* on NM_001024916.3) | Nonsense Mutation (SNP) | VAF 72/533 reads (14%) | called by muse, mutect2, varscan2
- CCHCR1 | c.2224+1del p.X742_splice | Splice Site (DEL) | VAF 158/422 reads (37%) | called by mutect2, pindel, varscan2
- HMCN1 | c.5423del p.A1808Efs*13 | Frame Shift Del (DEL) | VAF 30/135 reads (22%) | called by mutect2, pindel*
- LHCGR | c.1504del p.V503Sfs*7 | Frame Shift Del (DEL) | VAF 28/126 reads (22%) | called by mutect2, pindel, varscan2
- NEIL3 | c.1097C>A p.P366Q | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NLRP7 | c.814del p.D272Tfs*16 | Frame Shift Del (DEL) | VAF 27/103 reads (26%) | called by mutect2, pindel, varscan2
- NSD1 | c.2262del p.K754Nfs*14 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | called by mutect2, pindel, varscan2
- RBP3 | c.898G>T p.G300W | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCIN | c.1386del p.S463Pfs*21 (on ENST00000297029 / NM_001112706.3; = p.S216Pfs*21 on NM_033128.3) | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | called by pindel, varscan2
- TPTE | c.775T>G p.F259V (on ENST00000618007 / NM_199261.4; = p.F241V on NM_199259.4) | Missense Mutation (SNP) | VAF 58/510 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ZNF546 | c.2257_2259del p.E753del | In Frame Del (DEL) | VAF 23/96 reads (24%) | called by mutect2, pindel, varscan2
- AASDH | c.3072G>T p.P1024= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV99221996; called by muse, mutect2, varscan2
- ADAM29 | c.1044T>C p.R348= | Silent (SNP) | VAF 26/153 reads (17%) | catalogued as COSV100822303; called by muse, mutect2, varscan2
- ADAMTS20 | c.4486A>C p.R1496= | Silent (SNP) | VAF 30/57 reads (53%) | catalogued as COSV101240655; called by muse, mutect2, varscan2
- ADD2 | c.1758C>A p.A586= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100036673; called by muse, mutect2, varscan2
- AHCY | c.405C>T p.L135= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs199616559, COSV54154040; called by muse, mutect2, varscan2
- ALAS1 | c.1413C>T p.F471= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV59627395, COSV59628469; called by muse, mutect2, varscan2
- ANK2 | c.11793G>A p.E3931= | Silent (SNP) | VAF 35/121 reads (29%) | catalogued as COSV100004725; called by muse, mutect2, varscan2
- APOLD1 | c.825A>T p.A275= (on ENST00000326765 / NM_001130415.2; = p.A244= on NM_030817.3) | Silent (SNP) | VAF 43/91 reads (47%) | catalogued as COSV100458938; called by muse, mutect2, varscan2
- ARHGAP32 | c.4695C>T p.V1565= (on ENST00000310343 / NM_001378025.1; = p.V1216= on NM_014715.4) | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV100089707; called by muse, mutect2, varscan2
- AURKC | c.711A>G p.P237= (on ENST00000302804 / NM_001015878.2; = p.P203= on NM_003160.3) | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV100249044; called by muse, mutect2, varscan2
- CCDC9 | c.75G>T p.R25= | Silent (SNP) | VAF 33/112 reads (29%) | catalogued as COSV55721890, COSV99699912; called by muse, mutect2, varscan2
- CCN3 | c.597C>G p.V199= | Silent (SNP) | VAF 68/133 reads (51%) | catalogued as COSV52385055; called by muse, mutect2, varscan2
- CCNE2 | c.684C>G p.L228= | Silent (SNP) | VAF 39/159 reads (25%) | catalogued as COSV100353908, COSV57377444; called by muse, mutect2, varscan2
- CCT8L2 | c.591C>T p.S197= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as rs534377200, COSV63462073; called by muse, mutect2, varscan2
- CHRM2 | c.624C>T p.H208= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as rs1249636932, COSV100282142; called by muse, mutect2, varscan2
- CMIP | c.1461C>T p.L487= (on ENST00000537098 / NM_198390.2; = p.L393= on NM_030629.3) | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs368168220; called by muse, mutect2, varscan2
- CNGB3 | c.805C>T p.L269= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as rs1404033010, COSV100183302; called by muse, mutect2, varscan2
- CNOT4 | c.1329T>A p.T443= (on ENST00000315544 / NM_001190848.1; = p.T440= on NM_013316.4) | Silent (SNP) | VAF 87/179 reads (49%) | catalogued as COSV100212374; called by muse, mutect2, varscan2
- COL17A1 | c.954G>C p.V318= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV100793422; called by muse, mutect2, varscan2
- CYP4F11 | c.894C>T p.F298= | Silent (SNP) | VAF 51/177 reads (29%) | catalogued as COSV56127167; called by muse, mutect2, varscan2
- DAB2IP | c.3465G>T p.L1155= (on ENST00000408936; = p.L1127= on NM_032552.3) | Silent (SNP) | VAF 36/135 reads (27%) | catalogued as COSV52271158, COSV99406562; called by muse, mutect2, varscan2
- DCDC1 | c.4251C>T p.Y1417= (on ENST00000597505 / NM_001367979.1; = p.Y524= on NM_020869.3) | Silent (SNP) | VAF 89/182 reads (49%) | catalogued as rs375979270; called by muse, mutect2, varscan2
- DCUN1D4 | c.879G>A p.*293= (on ENST00000334635 / NM_001287757.1; = p.*258= on NM_015115.3) | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV100584772; called by muse, mutect2, varscan2
- DDX27 | c.2115C>G p.L705= | Silent (SNP) | VAF 7/165 reads (4%) | catalogued as COSV100871985; called by muse, mutect2
- DGCR2 | c.1578C>T p.S526= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs147091299; called by muse, mutect2
- DLG2 | c.459G>T p.V153= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV99720695; called by muse, mutect2, varscan2
- DNMT3A | c.1815C>T p.L605= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV53040009; called by muse, mutect2, varscan2
- DTX1 | c.1659G>T p.T553= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV99922223; called by muse, mutect2, varscan2
- ERBB3 | c.135A>G p.Q45= | Silent (SNP) | VAF 77/172 reads (45%) | catalogued as COSV99918130; called by muse, mutect2, varscan2
- FAM135B | c.3258G>A p.E1086= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as rs748971592, COSV52731032; called by muse, mutect2, varscan2
- FBF1 | c.117G>C p.A39= (on ENST00000586717; = p.A53= on NM_001319193.1) | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as COSV100045706, COSV59866914; called by muse, mutect2, varscan2
- FBXO24 | c.390C>T p.P130= (on ENST00000241071 / NM_033506.3; = p.P168= on NM_012172.5) | Silent (SNP) | VAF 37/152 reads (24%) | catalogued as rs1024093518, COSV53825229, COSV99575804; called by muse, mutect2, varscan2
- FGA | c.858C>A p.P286= | Silent (SNP) | VAF 20/128 reads (16%) | catalogued as COSV100120840; called by muse, mutect2, varscan2
- FLG | c.7347C>T p.S2449= | Silent (SNP) | VAF 172/459 reads (37%) | catalogued as rs986554144, COSV100912396, COSV64238246; called by muse, mutect2, varscan2
- FSCN3 | c.996C>G p.P332= | Silent (SNP) | VAF 47/201 reads (23%) | catalogued as COSV56170324, COSV99757420; called by muse, mutect2, varscan2
- GPR12 | c.450G>C p.S150= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV101198038, COSV67344432; called by muse, mutect2, varscan2
- GPR83 | c.327C>T p.F109= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs1294959444, COSV99704026; called by muse, mutect2, varscan2
- GRM8 | c.1938C>A p.I646= | Silent (SNP) | VAF 52/107 reads (49%) | catalogued as COSV100281398, COSV100286800; called by muse, mutect2, varscan2
- HAS3 | c.1230C>T p.L410= | Silent (SNP) | VAF 54/193 reads (28%) | catalogued as COSV99544872; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.162C>T p.S54= | Silent (SNP) | VAF 103/343 reads (30%) | called by muse, mutect2, varscan2
- IGKV1D-13 | c.69C>A p.A23= | Silent (SNP) | VAF 22/56 reads (39%) | called by mutect2, varscan2
- IL12RB1 | c.519G>T p.R173= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100443245; called by muse, mutect2, varscan2
- INSYN2A | c.909T>A p.T303= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV99733550; called by muse, mutect2, varscan2
- IRX3 | c.438C>G p.L146= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV100315447; called by muse, mutect2, varscan2
- ISL2 | c.1020C>A p.S340= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV99320934; called by muse, mutect2, varscan2
- ITIH2 | c.933C>T p.I311= | Silent (SNP) | VAF 54/147 reads (37%) | catalogued as rs1253146163, COSV64432203; called by muse, mutect2, varscan2
- ITPR2 | c.42C>T p.I14= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as rs1412379436, COSV54383705, COSV54387932; called by muse, mutect2, varscan2
- KAT14 | c.1893G>T p.T631= | Silent (SNP) | VAF 40/114 reads (35%) | catalogued as rs377654180, COSV66607865; called by muse, mutect2, varscan2
- KCNH2 | c.2077C>T p.L693= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as rs1380382303, COSV100061354; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNT2 | c.1392C>T p.T464= | Silent (SNP) | VAF 37/140 reads (26%) | catalogued as rs577209964, COSV54096309, COSV99657457; called by muse, mutect2, varscan2
- KIAA1522 | c.2259C>G p.V753= (on ENST00000373480 / NM_001198972.2; = p.V812= on NM_020888.3) | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV99615291; called by muse, mutect2, varscan2
- KIF1B | c.1611C>T p.L537= (on ENST00000377086 / NM_001365952.1; = p.L491= on NM_015074.3) | Silent (SNP) | VAF 36/135 reads (27%) | catalogued as COSV99824418; called by muse, mutect2, varscan2
- KLF4 | c.882C>T p.L294= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV101012789; called by muse, mutect2, varscan2
- KLRC2 | c.225C>A p.V75= | Silent (SNP) | VAF 28/281 reads (10%) | catalogued as COSV101122769, COSV67899623; called by muse, mutect2, varscan2
- LAMA4 | c.1737A>T p.L579= (on ENST00000230538 / NM_001105206.3; = p.L572= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as COSV100039761; called by muse, mutect2, varscan2
- LCMT1 | c.675C>T p.F225= | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as COSV101111841, COSV66725905; called by muse, mutect2, varscan2
- LILRA4 | c.993C>A p.G331= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as rs1193449934, COSV99393465; called by muse, mutect2, varscan2
- LILRB1 | c.762G>C p.L254= (on ENST00000427581; = p.L218= on NM_006669.6) | Silent (SNP) | VAF 49/166 reads (30%) | catalogued as COSV100208034; called by muse, mutect2, varscan2
- MASP1 | c.1614C>T p.T538= | Silent (SNP) | VAF 30/179 reads (17%) | catalogued as COSV100537722; called by muse, mutect2, varscan2
- MFSD14A | c.1164C>A p.L388= | Silent (SNP) | VAF 60/187 reads (32%) | catalogued as COSV99791170; called by muse, mutect2, varscan2
- MIIP | c.975G>A p.P325= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs765449595, COSV99337819; called by muse, mutect2, varscan2
- MLXIP | c.1959G>T p.A653= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV100039249; called by muse, mutect2
- MROH2B | c.4143G>C p.V1381= | Silent (SNP) | VAF 32/149 reads (21%) | catalogued as rs760761264, COSV101270967; called by muse, mutect2, varscan2
- MYH4 | c.1740C>T p.F580= | Silent (SNP) | VAF 115/181 reads (64%) | catalogued as COSV99702522; called by muse, mutect2, varscan2
- NKAPL | c.829T>C p.L277= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV100642600; called by muse, mutect2, varscan2
- NPIPA1 | c.984C>G p.L328= | Silent (SNP) | VAF 31/224 reads (14%) | catalogued as rs1327604311, COSV100047307; called by muse, varscan2
- NRAP | c.1908C>T p.N636= (on ENST00000359988 / NM_001322945.2; = p.N601= on NM_006175.4) | Silent (SNP) | VAF 54/116 reads (47%) | catalogued as rs372126033, COSV100748666; called by muse, mutect2, varscan2
- NRIP1 | c.33G>A p.V11= | Silent (SNP) | VAF 23/82 reads (28%) | catalogued as COSV100013255; called by muse, mutect2, varscan2
- OR13C2 | c.93C>A p.I31= | Silent (SNP) | VAF 38/174 reads (22%) | catalogued as COSV101604893; called by muse, mutect2, varscan2
- OR1K1 | c.798A>T p.R266= | Silent (SNP) | VAF 49/198 reads (25%) | catalogued as COSV99474417; called by muse, mutect2, varscan2
- OR4D6 | c.450G>C p.V150= | Silent (SNP) | VAF 61/184 reads (33%) | catalogued as COSV100271885; called by muse, mutect2, varscan2
- OR52E2 | c.969G>C p.T323= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV58611715, COSV58612319; called by muse, mutect2, varscan2
- OR56B4 | c.816G>A p.K272= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as COSV100337655, COSV57204071; called by muse, mutect2, varscan2
- OR6X1 | c.474G>A p.T158= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs533040898, COSV100020687; called by muse, mutect2, varscan2
- OR7D4 | c.171C>T p.T57= | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as COSV100432900; called by muse, mutect2, varscan2
- OR8D4 | c.807C>T p.T269= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as COSV100362008, COSV58429383; called by muse, mutect2, varscan2
- PAX1 | c.921C>G p.A307= | Silent (SNP) | VAF 38/153 reads (25%) | catalogued as COSV101270400; called by muse, mutect2, varscan2
- PCSK2 | c.1419G>A p.V473= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs1183359188, COSV99361021; called by muse, mutect2
- PCSK5 | c.1578G>C p.L526= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV100950833; called by muse, mutect2, varscan2
- PDE3A | c.2964C>A p.P988= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV100762958; called by muse, mutect2, varscan2
- PDE6C | c.816G>A p.L272= | Silent (SNP) | VAF 7/105 reads (7%) | catalogued as COSV101008877; called by muse, mutect2
- PEX19 | c.672C>T p.V224= | Silent (SNP) | VAF 51/288 reads (18%) | catalogued as COSV100926997; called by muse, mutect2, varscan2
- PIK3C2G | c.3642C>T p.I1214= (on ENST00000676171; = p.I1173= on NM_004570.5) | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV99854416; called by muse, mutect2, varscan2
- PON1 | c.678C>T p.I226= | Silent (SNP) | VAF 36/166 reads (22%) | catalogued as COSV99732685; called by muse, mutect2, varscan2
- PRPF18 | c.175T>C p.L59= | Silent (SNP) | VAF 41/119 reads (34%) | catalogued as COSV100187298; called by muse, mutect2, varscan2
- PTPRB | c.513C>A p.L171= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV100548209; called by muse, mutect2, varscan2
- RAB3IP | c.240T>A p.P80= (on ENST00000550536 / NM_175623.4; = p.P64= on NM_022456.5) | Silent (SNP) | VAF 57/125 reads (46%) | catalogued as COSV56082769, COSV99923781; called by muse, mutect2, varscan2
- RASGRF2 | c.45G>C p.L15= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV99430831; called by muse, mutect2, varscan2
- RDH8 | c.849G>A p.P283= (on ENST00000651512; = p.P263= on NM_015725.4) | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as rs778417867, COSV50674118; called by muse, mutect2, varscan2
- RNF220 | c.834G>A p.R278= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV100699110; called by muse, mutect2, varscan2
- RYR2 | c.1866G>C p.G622= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV100773289; called by muse, mutect2, varscan2
- SDK1 | c.3468G>A p.P1156= | Silent (SNP) | VAF 26/320 reads (8%) | catalogued as rs754657850, COSV67381977; called by muse, mutect2
- SGCZ | c.351C>A p.V117= | Silent (SNP) | VAF 91/357 reads (25%) | catalogued as COSV101172012, COSV66038081; called by muse, varscan2
- SHROOM4 | c.3198G>A p.A1066= | Silent (SNP) | VAF 27/44 reads (61%) | catalogued as rs781968129, COSV56788091, COSV99173192; called by muse, mutect2, varscan2
- SLC2A5 | c.702A>T p.L234= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV101072717; called by muse, mutect2, varscan2
- SLC30A10 | c.1188A>G p.L396= | Silent (SNP) | VAF 58/117 reads (50%) | catalogued as COSV100751615, COSV63070826; called by muse, mutect2, varscan2
- SLC35C1 | c.375C>T p.I125= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as rs747143721, COSV58480854; called by muse, mutect2, varscan2
- SNAPC2 | c.462G>C p.L154= | Silent (SNP) | VAF 15/149 reads (10%) | catalogued as COSV99564404; called by muse, mutect2, varscan2
- SPATA31E1 | c.465G>T p.L155= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100351231; called by muse, mutect2, varscan2
- SPHKAP | c.1425C>A p.V475= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV100764645; called by muse, mutect2, varscan2
- SPTA1 | c.1581C>T p.A527= | Silent (SNP) | VAF 39/79 reads (49%) | catalogued as rs1475021647, COSV100935762; called by muse, mutect2, varscan2
- SQOR | c.765C>T p.L255= | Silent (SNP) | VAF 55/187 reads (29%) | catalogued as COSV52943785, COSV99526247; called by muse, mutect2, varscan2
- STK31 | c.3000G>A p.T1000= | Silent (SNP) | VAF 43/155 reads (28%) | catalogued as rs371058322; called by muse, mutect2, varscan2
- SURF6 | c.717G>A p.L239= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as COSV100921222; called by muse, mutect2, varscan2
- TBC1D3B | c.690G>T p.G230= | Silent (SNP) | VAF 106/530 reads (20%) | called by muse, mutect2, varscan2
- THADA | c.4410C>A p.L1470= | Silent (SNP) | VAF 38/123 reads (31%) | catalogued as COSV100369680; called by muse, mutect2, varscan2
- TIMM23 | c.81G>T p.S27= | Silent (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- TNS3 | c.1380C>A p.A460= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV100236679; called by muse, mutect2, varscan2
- TRIL | c.492G>T p.G164= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100539011; called by mutect2, varscan2
- TRIM75P | c.67C>T p.L23= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs372455656; called by muse, mutect2
- TUBB4B | c.330G>A p.A110= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as rs148569376; called by muse, mutect2, varscan2
- USP53 | c.1098C>T p.I366= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as COSV99917856; called by muse, mutect2, varscan2
- USP8 | c.2286T>A p.I762= | Silent (SNP) | VAF 27/116 reads (23%) | catalogued as COSV100209409; called by muse, mutect2, varscan2
- VGLL2 | c.10C>T p.L4= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100410055; called by muse, mutect2, varscan2
- VPS39 | c.816G>A p.P272= (on ENST00000348544 / NM_001301138.2; = p.P261= on NM_015289.5) | Silent (SNP) | VAF 37/107 reads (35%) | catalogued as rs138294459; called by muse, mutect2, varscan2
- WDHD1 | c.1611C>A p.A537= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as COSV100777671; called by muse, mutect2, varscan2
- ZIM3 | c.828G>A p.K276= | Silent (SNP) | VAF 53/171 reads (31%) | catalogued as COSV54143897, COSV99518852; called by muse, mutect2, varscan2
- ZKSCAN4 | c.729C>T p.N243= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as COSV101043608; called by muse, mutect2, varscan2
- ZNF235 | c.1374A>T p.P458= | Silent (SNP) | VAF 43/170 reads (25%) | catalogued as COSV99349799; called by muse, mutect2, varscan2
- ZNF555 | c.1521C>G p.L507= | Silent (SNP) | VAF 29/122 reads (24%) | catalogued as COSV100514802; called by muse, mutect2, varscan2
- ZP2 | c.258G>A p.P86= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as rs150656642; called by muse, mutect2, varscan2
- C7orf66 | n.269C>T | RNA (SNP) | VAF 118/262 reads (45%) | called by muse, mutect2, varscan2
- ENPP2 | c.973-2031A>T | Intron (SNP) | VAF 61/176 reads (35%) | catalogued as COSV50018554; called by muse, mutect2, varscan2
- LEKR1 | c.*1190G>T | 3'UTR (SNP) | VAF 29/90 reads (32%) | catalogued as COSV100739437; called by muse, mutect2, varscan2
- LRP5L | n.532C>T | RNA (SNP) | VAF 27/69 reads (39%) | catalogued as rs769869319, COSV101292713; called by muse, mutect2, varscan2
- SMCO1 | c.-1G>A | 5'UTR (SNP) | VAF 10/108 reads (9%) | catalogued as COSV101285039; called by muse, mutect2
- SNORD113-4 | n.56T>C | RNA (SNP) | VAF 92/148 reads (62%) | called by muse, mutect2, varscan2
- TP63 | c.1350-6267T>C | Intron (SNP) | VAF 29/102 reads (28%) | catalogued as COSV99289343; called by muse, mutect2, varscan2
